Somatic mutation profile of tumor specimen TCGA-GJ-A3OU-01A (aliquot TCGA-GJ-A3OU-01A-31D-A382-10) from TCGA case TCGA-GJ-A3OU, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, clear cell type; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 59.3 years (21,671 days).
Specimen TCGA-GJ-A3OU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) adf6826b-b3b5-46ea-92c7-5acee0af3184.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GJ-A3OU-10A (Blood Derived Normal), aliquot TCGA-GJ-A3OU-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95c22d3d-f41e-420f-80ee-a253381918e7

The open-access MAF lists 61 somatic variants for this specimen: 48 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 10, Intron 2, Nonsense Mutation 2, Splice Site 1, 5'UTR 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.823T>C p.C275R | Missense Mutation (SNP) | VAF 12/71 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519983, COSV52700773, COSV52771673; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACBD6 | c.137T>G p.F46C | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100852466; called by muse, mutect2, varscan2
- ACTL9 | c.241T>A p.C81S | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.073); catalogued as COSV100185278; called by muse, mutect2, varscan2
- ANKRD13A | c.707T>G p.L236R | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99923947; called by muse, mutect2, varscan2
- ASB10 | c.566G>T p.R189L (on ENST00000420175 / NM_001142459.2; = p.R174L on NM_080871.4) | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.297); catalogued as COSV99318550; called by muse, mutect2
- ASH1L | c.3592C>A p.P1198T | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100853382; called by muse, mutect2, varscan2
- C1orf112 | c.479-1G>C p.X160_splice | Splice Site (SNP) | VAF 11/51 reads (22%) | catalogued as COSV99609697; called by muse, varscan2
- CACNA1D | c.4942C>T p.H1648Y (on ENST00000350061 / NM_001128840.3; = p.H1668Y on NM_000720.4) | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99857832; called by muse, mutect2, varscan2
- CACNA1H | c.1124T>A p.I375N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100672188; called by muse, mutect2, varscan2
- CACNA2D2 | c.1216C>A p.R406S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99817488; called by muse, mutect2, varscan2
- CCDC125 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV101143573, COSV67288335; called by muse, mutect2, varscan2
- CDC5L | c.1884G>C p.E628D | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV101014998; called by muse, mutect2, varscan2
- CHRNA3 | c.923T>G p.L308R | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100468209; called by muse, mutect2, varscan2
- COL9A1 | c.1610C>T p.T537M | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs141895443, COSV57888254; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COQ8A | c.1902G>T p.E634D | Missense Mutation (SNP) | VAF 98/1030 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV100504846; called by muse, mutect2
- COX20 | c.13C>G p.P5A | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV100834668; called by muse, varscan2
- CSMD1 | c.9145C>T p.Q3049* (on ENST00000520002; = p.Q3048* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 19/347 reads (5%) | catalogued as COSV100147002; called by muse, mutect2
- FOXP1 | c.1894C>A p.P632T | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.297); catalogued as COSV100561519; called by muse, mutect2, varscan2
- GALNT12 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777425926, COSV100899124; called by muse, mutect2, varscan2
- GALNT3 | c.397T>G p.L133V | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs763127846, COSV101204914; called by muse, mutect2, varscan2
- H1-1 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.928); catalogued as COSV99772003; called by muse, mutect2
- H2AC11 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.917); catalogued as rs751969992, COSV60362716; called by muse, mutect2, varscan2
- HECW1 | c.182T>C p.V61A | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.049); catalogued as COSV101223395; called by muse, mutect2, varscan2
- HIVEP3 | c.2782C>A p.L928M | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99912402; called by muse, mutect2
- HRH3 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.23); catalogued as COSV100420557, COSV58048878; called by muse, mutect2, varscan2
- KCTD8 | c.845G>T p.R282L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.38); catalogued as COSV100759493, COSV63591325; called by muse, mutect2, varscan2
- LPCAT2 | c.453T>A p.D151E | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100044762; called by muse, mutect2, varscan2
- MAGEA6 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.159); catalogued as rs782541530, COSV100262662; called by muse, mutect2, varscan2
- MGLL | c.351C>G p.F117L (on ENST00000398104 / NM_001003794.2; = p.F127L on NM_007283.6) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as rs1224590652, COSV99411782; called by muse, mutect2, varscan2
- MTA2 | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 16/123 reads (13%) | catalogued as COSV99604249; called by muse, mutect2, varscan2
- MTMR4 | c.448C>A p.Q150K | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100050978; called by muse, mutect2, varscan2
- NDUFAF5 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as rs142611230; called by muse, mutect2, varscan2
- NEDD1 | c.1030G>C p.A344P | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1398471335; called by muse, mutect2, varscan2
- NEK2 | c.878C>G p.P293R | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100878614; called by muse, mutect2, varscan2
- NLRP7 | c.2890G>T p.D964Y (on ENST00000340844 / NM_206828.3; = p.D993Y on NM_139176.3) | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV100052442, COSV60173313; called by muse, mutect2
- PCDHA5 | c.2246A>G p.Y749C | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.043); catalogued as COSV100972246; called by muse, mutect2
- PCDHA7 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs782412740, COSV100971442; called by muse, mutect2
- PI15 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290077108, COSV99477976; called by muse, mutect2, varscan2
- POLA1 | c.3949G>A p.A1317T | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0.012); catalogued as COSV100985329; called by muse, mutect2
- PRPH | c.1352T>G p.V451G | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99141968; called by muse, mutect2
- RGS1 | c.114G>A p.M38I | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1355381710, COSV100817451; called by muse, mutect2
- SLC44A3 | c.779G>C p.W260S (on ENST00000271227 / NM_001114106.3; = p.W212S on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99598076; called by muse, mutect2
- SLC8A1 | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60482154; called by muse, mutect2
- SPTA1 | c.1040A>G p.D347G | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV100934791; called by muse, mutect2, varscan2
- TRAF3 | c.819G>A p.K273= | Splice Region (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100693574, COSV61024210; called by muse, mutect2, varscan2
- WNT9B | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV99255140, COSV99255272; called by muse, mutect2, varscan2
- ZNF432 | c.1451C>G p.P484R | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99659223; called by muse, mutect2, varscan2
- CPSF4 | c.327dup p.C110Mfs*19 | Frame Shift Ins (INS) | VAF 23/107 reads (21%) | called by mutect2, pindel, varscan2
- APBA1 | c.1692T>A p.P564= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV99595943; called by muse, mutect2, varscan2
- COL5A3 | c.36C>G p.A12= | Silent (SNP) | VAF 19/128 reads (15%) | catalogued as rs1194331140, COSV99318742; called by muse, mutect2, varscan2
- CPA5 | c.1110C>T p.I370= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100812294, COSV62569219; called by muse, mutect2, varscan2
- MTA2 | c.642G>A p.R214= | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as COSV53875021; called by muse, mutect2, varscan2
- SAA2 | c.366C>T p.Y122= | Silent (SNP) | VAF 10/103 reads (10%) | catalogued as COSV99879301; called by muse, mutect2
- SNTG2 | c.1173C>A p.I391= | Silent (SNP) | VAF 19/156 reads (12%) | catalogued as COSV100422235, COSV58013541; called by muse, mutect2, varscan2
- UGGT1 | c.882C>T p.H294= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV99390621; called by muse, mutect2, varscan2
- VRK2 | c.42A>G p.P14= | Silent (SNP) | VAF 20/173 reads (12%) | catalogued as COSV100417825; called by muse, mutect2, varscan2
- XRN1 | c.5061T>A p.S1687= | Silent (SNP) | VAF 22/137 reads (16%) | catalogued as COSV99377832; called by muse, mutect2, varscan2
- ZNF317 | c.198T>C p.F66= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as COSV99927069; called by muse, mutect2, varscan2
- FBXL18 | c.2000+1332G>T | Intron (SNP) | VAF 24/152 reads (16%) | catalogued as COSV101212054; called by muse, mutect2
- GUK1 | c.-175del | 5'UTR (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- RBM44 | c.-98-1947A>G | Intron (SNP) | VAF 14/183 reads (8%) | catalogued as COSV100389805; called by muse, mutect2
